Somatic mutation profile of tumor specimen TCGA-A4-7583-01A (aliquot TCGA-A4-7583-01A-11D-2136-08) from TCGA case TCGA-A4-7583, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.1 years (21,962 days).
Specimen TCGA-A4-7583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d7e2598-72bc-49fb-ac99-a2ace88935c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7583-10A (Blood Derived Normal), aliquot TCGA-A4-7583-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b130685-407f-4eb5-b3f8-1fddb6185611

The open-access MAF lists 64 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Ins 4, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs879254630, CM920421, CM950756, CM994425, COSV52941402; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAR | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52711792; called by muse, mutect2, varscan2
- ADCY5 | c.3219G>A p.M1073I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV59193380; called by mutect2, varscan2
- AP1M1 | c.924C>G p.N308K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52224582; called by muse, mutect2, varscan2
- ARID3C | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV52406232; called by muse, mutect2, varscan2
- CCT7 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57821236; called by muse, mutect2, varscan2
- CLDN18 | c.347A>T p.N116I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV51735646; called by muse, mutect2, varscan2
- CMTR2 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV57602407; called by muse, mutect2, varscan2
- COL18A1 | c.3316G>A p.D1106N (on ENST00000359759 / NM_130444.3; = p.D871N on NM_030582.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV60586069; called by muse, mutect2, varscan2
- COL18A1 | c.3317A>T p.D1106V (on ENST00000359759 / NM_130444.3; = p.D871V on NM_030582.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV60586083; called by muse, mutect2, varscan2
- DLX3 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV71547276; called by muse, mutect2, varscan2
- EYS | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as COSV60975287; called by muse, mutect2, varscan2
- GAS6 | c.1946A>G p.N649S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59846732; called by muse, mutect2, varscan2
- GORASP2 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV52200656; called by muse, mutect2, varscan2
- KLHL4 | c.167C>G p.S56C | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.345); catalogued as COSV100909060, COSV64138628; called by muse, mutect2, varscan2
- NANS | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV52962815; called by muse, mutect2, varscan2
- NOVA2 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV54355678; called by muse, mutect2
- NPC1 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV52575905, COSV52579752; called by muse, mutect2, varscan2
- PBRM1 | c.4558C>A p.P1520T (on ENST00000296302 / NM_001366071.2; = p.P1413T on NM_018313.5) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV56259014; called by muse, mutect2, varscan2
- PHF21B | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV57555221; called by muse, mutect2, varscan2
- PLCG2 | c.3592T>G p.S1198A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV63867001; called by muse, mutect2, varscan2
- PSD3 | c.2676A>T p.K892N (on ENST00000440756; = p.K891N on NM_015310.4) | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV54065642; called by muse, mutect2, varscan2
- RBM23 | c.455+1G>C p.X152_splice (on ENST00000359890 / NM_001077351.2; = p.X136_splice on NM_018107.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 23/35 reads (66%) | catalogued as COSV57126739; called by muse, mutect2, varscan2
- RUSC2 | c.873G>C p.M291I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV63427488; called by muse, mutect2, varscan2
- SATB2 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53477283; called by muse, varscan2
- SLC10A6 | c.679C>G p.L227V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV56720487; called by muse, mutect2, varscan2
- SLC22A16 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as COSV57926846, COSV57933921; called by muse, mutect2, varscan2
- SMG1 | c.9289C>A p.L3097I | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV67169191; called by muse, mutect2, varscan2
- SUN3 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs1346478067, COSV52048303; called by muse, mutect2, varscan2
- TENT2 | c.1217G>C p.S406T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57134408; called by muse, varscan2
- THNSL1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs760568760, COSV64478855; called by muse, mutect2, varscan2
- TLR3 | c.1252A>C p.K418Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.078); catalogued as COSV57167254; called by muse, mutect2, varscan2
- TMEM41A | c.723A>T p.K241N | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV53982689; called by muse, mutect2, varscan2
- TRIM35 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV57749077; called by muse, mutect2, varscan2
- TULP3 | c.1256A>C p.N419T | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as COSV68117268; called by muse, mutect2, varscan2
- UBOX5 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53903995; called by muse, mutect2, varscan2
- ZFR | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV54049917; called by muse, mutect2, varscan2
- ZNF395 | c.1351A>G p.S451G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1313816836, COSV60427629; called by muse, mutect2, varscan2
- BPIFB2 | c.576dup p.G193Wfs*8 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, pindel, varscan2
- DOLK | c.638_639insC p.T214Dfs*142 | Frame Shift Ins (INS) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- HABP2 | c.1058_1064del p.H353Pfs*12 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- HAO1 | c.690_691insAAA p.S230_L231insK | In Frame Ins (INS) | VAF 51/166 reads (31%) | called by mutect2, pindel, varscan2
- HDGF | c.149dup p.G51Rfs*63 | Frame Shift Ins (INS) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- KIR3DL2 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MAST3 | c.2283_2284dup p.C762Sfs*18 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- PROM1 | c.2129_2130+2del p.X710_splice | Splice Site (DEL) | VAF 62/203 reads (31%) | called by mutect2, pindel, varscan2
- RNF165 | c.260_262del p.T87_L88delinsM | In Frame Del (DEL) | VAF 11/46 reads (24%) | called by pindel, varscan2
- SAMD4B | c.1362_1371del p.P455Afs*21 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel, varscan2
- ZNHIT3 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ACAD10 | c.2130T>C p.A710= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV58153386; called by muse, mutect2, varscan2
- CAMK2D | c.942C>T p.F314= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV56425423; called by muse, mutect2, varscan2
- CCT7 | c.570G>T p.L190= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57821230; called by muse, mutect2, varscan2
- CENATAC | c.147C>T p.R49= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57722039; called by mutect2, varscan2
- CLCA2 | c.85C>T p.L29= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as COSV65285837; called by muse, varscan2
- ETV1 | c.606G>C p.T202= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV54135981; called by muse, mutect2, varscan2
- IGKV1D-17 | c.141G>A p.A47= | Silent (SNP) | VAF 46/323 reads (14%) | catalogued as rs767720425; called by muse, mutect2, varscan2
- NELFE | c.753A>G p.S251= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV64810024; called by muse, mutect2, varscan2
- NOP58 | c.600T>C p.D200= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV51895359; called by muse, mutect2, varscan2
- PEX1 | c.216T>C p.N72= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV50394489; called by muse, mutect2, varscan2
- PIK3R1 | c.849T>G p.T283= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV57122872; called by muse, mutect2, varscan2
- SETD4 | c.489A>G p.R163= | Silent (SNP) | VAF 80/183 reads (44%) | catalogued as COSV59770934; called by muse, mutect2, varscan2
- TBCD | c.2664G>C p.R888= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV62797216; called by muse, mutect2, varscan2
- TTN | c.89676T>C p.D29892= (on ENST00000591111; = p.D22468= on NM_003319.4) | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs764363274, COSV59864091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBCK1 | c.167+402_167+421del | Intron (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
